Somatic mutation profile of tumor specimen TCGA-3X-AAV9-01A (aliquot TCGA-3X-AAV9-01A-72D-A417-09) from TCGA case TCGA-3X-AAV9, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 72.1 years (26,349 days).
Specimen TCGA-3X-AAV9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcc976ae-ddc5-4b18-903f-12c614225e06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3X-AAV9-10A (Blood Derived Normal), aliquot TCGA-3X-AAV9-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4996a260-1164-4ce4-ae4d-91fe61e374b6

The open-access MAF lists 44 somatic variants for this specimen: 30 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 12, Nonsense Mutation 6, 3'UTR 1, Splice Region 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RASA1 | c.2125C>T p.R709* | Nonsense Mutation (SNP) | VAF 24/116 reads (21%) | catalogued as rs1554049422, CM083069, COSV57191908; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APOB | c.2479C>A p.L827I | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as COSV51941726; called by muse, mutect2, varscan2
- CEP95 | c.2417C>G p.S806C | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs782669275; called by muse, mutect2
- DOCK7 | c.2684G>A p.R895Q | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs573187574; called by muse, mutect2, varscan2
- EZH2 | c.844C>A p.H282N | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV100234659; called by muse, mutect2
- GSTK1 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1205620193, COSV64424472, COSV64424545; called by muse, mutect2
- MAP3K11 | c.1731G>C p.Q577H | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.827); catalogued as COSV100482543, COSV58421794; called by muse, mutect2
- MICALL1 | c.1549G>C p.E517Q | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs1415694496; called by muse, mutect2
- OR2T12 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs138674715; called by muse, mutect2, varscan2
- PKHD1 | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as rs765251347, CM100548, COSV61885249; called by muse, mutect2, varscan2
- TENM2 | c.7175C>T p.T2392M (on ENST00000518659 / NM_001122679.2; = p.T2153M on NM_001080428.3) | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1268422632, COSV69136489; called by muse, mutect2
- TRUB1 | c.885G>A p.W295* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as COSV53931248; called by muse, mutect2, varscan2
- ZNF208 | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 5/53 reads (9%) | catalogued as rs765113757; called by mutect2, varscan2
- ZNF610 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as rs1394874778; called by muse, mutect2, varscan2
- ALPK3 | c.3518G>C p.R1173T | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2
- ARHGEF38 | c.561C>G p.Y187* | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2, varscan2
- ASCC1 | c.406C>T p.Q136* (on ENST00000342444 / NM_001369085.1; = p.Q108* on NM_001198798.2 and 8 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 11/108 reads (10%) | called by muse, mutect2
- CSF1R | c.1197A>G p.R399= | Splice Region (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- ELK1 | c.1137G>C p.W379C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EML5 | c.313C>A p.H105N | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- KIF19 | c.519G>T p.E173D | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- KYNU | c.1282C>G p.R428G | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC71 | c.1420C>T p.L474F | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MAGEC1 | c.1412A>T p.E471V | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- N4BP2 | c.3002A>G p.Q1001R | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SCN7A | c.3433A>G p.I1145V | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- SCNN1A | c.847C>A p.R283S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- SPTBN1 | c.3206G>T p.R1069L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- TAS2R20 | c.354del p.H119Ifs*3 | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | called by mutect2, pindel
- TRHDE | c.2443A>G p.R815G | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ABCC9 | c.36A>G p.S12= | Silent (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2, varscan2
- CHRNB1 | c.978T>C p.S326= | Silent (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2
- ENOX1 | c.819G>A p.L273= | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- GALNT14 | c.696C>T p.N232= | Silent (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- HLA-F | c.972C>T p.V324= | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as rs566982053; called by muse, mutect2
- HYDIN | c.4497C>T p.P1499= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs752659967; called by muse, mutect2, varscan2
- KCNJ14 | c.1143C>T p.F381= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- KHK | c.84G>A p.S28= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs1414020826; called by muse, mutect2, varscan2
- MAP3K1 | c.3339C>T p.F1113= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV68124434; called by muse, mutect2
- NUMBL | c.693G>A p.G231= | Silent (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
- PTPN14 | c.1884C>T p.L628= | Silent (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2
- TMED8 | c.436C>T p.L146= | Silent (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- PARGP1 | n.2089A>C | RNA (SNP) | VAF 65/613 reads (11%) | called by muse, mutect2, varscan2
- XIRP2 | c.*1427G>C | 3'UTR (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
